Somatic mutation profile of tumor specimen BA2597D (aliquot aq-BA2597D) from BEATAML1.0 case 2290, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.5 years (29,043 days).
Specimen BA2597D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c82b90-0b35-4de3-9b13-07f95c54f2e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2039D (Solid Tissue Normal), aliquot aq-BA2039D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5c49aa4-5263-4b2e-a1d2-b9c1c3bb24f8

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 38/133 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs77375493, CM123094, COSV67569051, COSV67571909; ClinVar: risk factor / pathogenic / likely pathogenic / not provided / affects; called by muse, mutect2, varscan2
- MPL | c.1544G>T p.W515L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs121913615, COSV65243776, COSV65245195; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AQP2 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM137423; called by muse, mutect2
- MDM1 | c.1528G>T p.G510* | Nonsense Mutation (SNP) | VAF 47/121 reads (39%) | called by muse, varscan2
